CGCI case BLGSP-71-22-00334 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ae39efc-1b2a-4ecf-aff7-edcec577abbf

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 4.6 years (1,677 days); Year of diagnosis: 2014; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 694 days (1.9 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Small intestine; Sites of involvement: Small intestine.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Retroperitoneal; Tumor largest dimension diameter: 4 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ANHL1131 (Group B + rituximab); Days to treatment start: 7 days; Days to treatment end: 105 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 7 days; Days to treatment end: 105 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50.
- Days to follow up: 694 days (1.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL2: Equivocal.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6: Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Ki67: Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 761 [Blood test normal range upper: 345].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 15.5 kg; Height: 103 cm; BMI: 14.6.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-22-00334-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Surgical Resection; Tissue collection type: Prospective.
  Slide BLGSP-71-22-00334-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 75; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-22-00334-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-22-00334-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 761; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: ANHL1131 (Group B+ rituximab); Pharma adjuvant cycles count: 4.
